Gene-level copy-number profile of tumor specimen C3L-01232-03 from CPTAC case C3L-01232, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.6 years (18,836 days).
Specimen C3L-01232-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4236f3f4-8390-4ac6-9588-a077fad55d44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01232-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/59bdfe1e-e411-425e-8455-1a63520c9f33

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 4; copy number 2: 8,376; copy number 3: 21; copy number 4: 44,699; copy number 5: 2,344; copy number 6: 2,927; copy number 7: 6.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:56,244,009–57,299,281, 21 genes (within-gene range 0–2): TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1, AC010999.2, AC010999.1, TCF12, HNRNPA3P11, SNORD13D.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
